Somatic mutation profile of tumor specimen ALCH-B0B9-TTP1-A (aliquot ALCH-B0B9-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0B9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.7 years (25,101 days).
Specimen ALCH-B0B9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f347798-db7a-4052-8ac9-7ef1b7463048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0B9-NB1-A (Blood Derived Normal), aliquot ALCH-B0B9-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3858a745-1d50-4f14-9ecd-523c1d4afb01

The open-access MAF lists 312 somatic variants for this specimen: 210 protein-altering or splice-affecting, 67 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 67, Nonsense Mutation 15, Intron 14, Frame Shift Del 8, 3'UTR 8, RNA 6, 3'Flank 4, Splice Region 2, 5'UTR 2, Frame Shift Ins 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202688, CM110139, COSV64307520; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 72/374 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM19 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99976298; called by muse, mutect2
- ADAM7 | c.1385C>G p.P462R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs765178430, COSV51537362; called by muse, mutect2, varscan2
- ARHGAP30 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240000857, COSV100920184; called by muse, mutect2
- BCOR | c.3613C>A p.P1205T (on ENST00000378444 / NM_001123385.2; = p.P1171T on NM_017745.6) | Missense Mutation (SNP) | VAF 259/584 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV60707167; called by muse, mutect2, varscan2
- CBL | c.1223G>T p.W408L | Missense Mutation (SNP) | VAF 59/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50643606, COSV50645120, COSV50667071; called by muse, mutect2, varscan2
- CCDC168 | c.4828A>G p.I1610V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs1192161575; called by muse, mutect2, varscan2
- CNOT1 | c.5836C>T p.L1946F | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55321309; called by muse, mutect2, varscan2
- COL3A1 | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58585651; called by muse, mutect2, varscan2
- CSMD3 | c.4556A>T p.Q1519L (on ENST00000297405 / NM_001363185.1; = p.Q1415L on NM_052900.3) | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV99836950; called by muse, mutect2, varscan2
- CTNND2 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100479225; called by muse, mutect2
- DEFA4 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.807); catalogued as rs369645748; called by muse, mutect2, varscan2
- DMD | c.971C>A p.A324D | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs749880195; called by muse, mutect2, varscan2
- EARS2 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV104437636; called by muse, mutect2
- EEF2K | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442956056, COSV53783273; called by muse, varscan2
- ERICH3 | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV100445235; called by muse, mutect2, varscan2
- F5 | c.1400G>T p.R467M | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV100889207; called by muse, mutect2, varscan2
- FAT3 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV53074488; called by muse, mutect2, varscan2
- GDPD3 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1011410926, COSV53775463; called by muse, mutect2, varscan2
- GLA | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 22/397 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as CM078384, CM165583; called by muse, mutect2
- H4C4 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV61590919, COSV61591605; called by muse, mutect2
- HERC2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs780572301; called by muse, mutect2, varscan2
- HGF | c.1990A>T p.I664F | Missense Mutation (SNP) | VAF 70/412 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs761664295; called by muse, mutect2, varscan2
- HOOK1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs144341495, COSV100968954; called by muse, mutect2, varscan2
- IGSF1 | c.1058C>A p.A353E | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.345); catalogued as COSV63840025; called by muse, mutect2, varscan2
- IRS4 | c.3251G>C p.R1084P | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64533078; called by muse, mutect2
- KCNIP1 | c.170C>A p.T57N (on ENST00000411494 / NM_001034837.3; = p.T46N on NM_014592.4) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1427198224, COSV61088268; called by muse, mutect2, varscan2
- KHDRBS3 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63419079; called by muse, mutect2
- KIAA1549L | c.4318C>T p.P1440S (on ENST00000321505; = p.P1737S on NM_012194.3) | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs1411669320; called by muse, mutect2, varscan2
- KIF1A | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.291); catalogued as rs752556549; called by mutect2, varscan2
- KTN1 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV68025690; called by muse, mutect2, varscan2
- LRP1B | c.3475G>C p.G1159R | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67197477, COSV67198049; called by muse, mutect2, varscan2
- MALSU1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.11); catalogued as COSV54978932; called by muse, mutect2, varscan2
- MUC16 | c.26347G>A p.A8783T | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.047); catalogued as rs1364707886; called by muse, mutect2
- MYH7 | c.5287G>A p.A1763T | Missense Mutation (SNP) | VAF 28/510 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs727504355, CM1411014, COSV62515978; ClinVar: uncertain significance; called by muse, mutect2
- MYO18A | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs763171966, COSV100572873; called by muse, mutect2
- NRXN1 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs796052776, COSV58448967; ClinVar: uncertain significance; called by muse, mutect2
- OR6P1 | c.169C>A p.R57S | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV100583243; called by muse, mutect2, varscan2
- PER2 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs376910199; called by muse, mutect2, varscan2
- PIGN | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748175836; called by muse, mutect2, varscan2
- SEMA3C | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54843221; called by muse, mutect2, varscan2
- SERPINB7 | c.668C>A p.S223* | Nonsense Mutation (SNP) | VAF 30/245 reads (12%) | catalogued as rs376421072; called by muse, varscan2
- SHISA9 | c.1122C>A p.N374K | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs762019715; called by muse, mutect2, varscan2
- SLC9A2 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 17/138 reads (12%) | catalogued as rs769703806; called by muse, mutect2, varscan2
- SNTB1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 96/456 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV67325898; called by muse, varscan2
- SNX31 | c.980del p.G327Efs*17 | Frame Shift Del (DEL) | VAF 28/155 reads (18%) | catalogued as COSV61263300; called by mutect2, pindel, varscan2
- SYT16 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs374891288; called by muse, mutect2, varscan2
- TCF19 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1417253315; called by mutect2, varscan2
- TRIM51GP | c.592T>A p.L198M | Missense Mutation (SNP) | VAF 62/385 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs764471135; called by muse, mutect2, varscan2
- VWDE | c.1852G>T p.G618* | Nonsense Mutation (SNP) | VAF 28/148 reads (19%) | catalogued as COSV51733118; called by muse, varscan2
- ZFHX4 | c.7498G>T p.V2500F | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV99267084; called by muse, mutect2, varscan2
- ZNF423 | c.3065G>T p.R1022L (on ENST00000563137 / NM_001379286.1; = p.R1014L on NM_015069.4) | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV52183625; called by muse, mutect2
- ZNF479 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1554400363; called by muse, mutect2, varscan2
- ZNF668 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.611); catalogued as rs1382541153, COSV100336936; called by muse, mutect2, varscan2
- A2M | c.3217A>T p.R1073W | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ABCC6 | c.3044G>T p.R1015L | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACIN1 | c.3251C>A p.A1084D | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADAMTS12 | c.936C>A p.H312Q | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF2 | c.3267+2T>G p.X1089_splice | Splice Site (SNP) | VAF 35/154 reads (23%) | called by muse, mutect2, varscan2
- AGBL4 | c.156T>C p.S52= | Splice Region (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- ANKS1B | c.1142C>A p.T381K | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ASPM | c.6635_6636del p.L2212* | Frame Shift Del (DEL) | VAF 34/231 reads (15%) | called by mutect2, pindel, varscan2
- BCAT1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BMPER | c.1901T>G p.V634G | Missense Mutation (SNP) | VAF 75/465 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- BTBD7 | c.2261del p.F754Sfs*67 | Frame Shift Del (DEL) | VAF 50/163 reads (31%) | called by mutect2, pindel, varscan2
- C20orf194 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D1 | c.3106C>T p.Q1036* (on ENST00000356253 / NM_001366867.1; = p.Q1024* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 60/343 reads (17%) | called by muse, mutect2, varscan2
- CADM3 | c.590A>T p.Q197L (on ENST00000368125 / NM_001127173.3; = p.Q231L on NM_021189.5) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CAPN5 | c.517G>T p.D173Y (on ENST00000456580; = p.D133Y on NM_004055.5) | Missense Mutation (SNP) | VAF 54/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CARF | c.1394T>C p.F465S | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- CCDC141 | c.3420G>T p.L1140F | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); called by muse, varscan2
- CCDC185 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CD4 | c.799A>C p.T267P | Missense Mutation (SNP) | VAF 102/299 reads (34%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- CDKN2A | c.150+5G>C | Splice Region (SNP) | VAF 55/252 reads (22%) | called by muse, mutect2, varscan2
- CDR1 | c.108C>A p.D36E | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CFAP20DC | c.909G>C p.E303D (on ENST00000482387 / NM_001351530.2; = p.E178D on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CHST1 | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CHST2 | c.1562G>C p.S521T | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); called by muse, mutect2
- COL3A1 | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 50/310 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A3 | c.653A>T p.H218L | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A6 | c.2569C>A p.P857T | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CTNNA3 | c.2589G>T p.K863N | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CTNNA3 | c.242C>G p.T81R | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DAOA | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DCC | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DIAPH2 | c.2589G>C p.K863N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- DNAJA3 | c.1169G>C p.G390A | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPEP2 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- E2F7 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- EHHADH | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELAVL4 | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- EN2 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ERCC6L | c.51G>T p.Q17H | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ERICH5 | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- ESR1 | c.303C>A p.N101K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- EVI5 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- FAM222B | c.412_429del p.T138_T143del | In Frame Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- FAT3 | c.1145A>T p.D382V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- FPR3 | c.771T>A p.Y257* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- FRG2C | c.848G>T p.*283Lext*11 | Nonstop Mutation (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- GABRQ | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBA | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- GCNA | c.1345G>T p.V449L | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- GLI2 | c.3167_3169delinsT p.H1056Lfs*22 (on ENST00000361492 / NM_001374353.1; = p.H1073Lfs*22 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 43/359 reads (12%) | called by pindel, varscan2*
- GOLGB1 | c.2911C>G p.Q971E | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HERC2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- HUWE1 | c.4944C>A p.S1648R | Missense Mutation (SNP) | VAF 20/415 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2
- HYAL4 | c.984T>A p.S328R | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ICE1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 135/328 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- IFNL3 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- IGF2BP1 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGKV1D-17 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 39/541 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- INSIG1 | c.701A>T p.Y234F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITPKC | c.438G>C p.W146C | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAKMIP1 | c.2489G>T p.W830L | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KARS1 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- KBTBD3 | c.720dup p.V241Sfs*8 | Frame Shift Ins (INS) | VAF 18/168 reads (11%) | called by pindel, varscan2
- KBTBD3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 22/156 reads (14%) | called by muse, varscan2
- KIF17 | c.2403C>A p.Y801* | Nonsense Mutation (SNP) | VAF 44/291 reads (15%) | called by muse, mutect2, varscan2
- KLHL6 | c.728del p.V243Afs*80 | Frame Shift Del (DEL) | VAF 38/228 reads (17%) | called by mutect2, pindel, varscan2
- LGI4 | c.1540del p.R514Afs*55 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
- LRRC28 | c.725T>A p.V242E | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC72 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2
- LRRTM3 | c.640C>A p.H214N | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYPD6 | c.498G>C p.W166C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.178); called by muse, mutect2
- MAGI2 | c.1865G>C p.S622T | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MARCHF6 | c.1599G>T p.Q533H | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MC3R | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MRPL9 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MTUS2 | c.2753C>G p.T918R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MYH15 | c.2876G>A p.C959Y | Missense Mutation (SNP) | VAF 61/365 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- MYOM3 | c.2465G>A p.W822* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- NEUROD4 | c.33G>T p.M11I | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- NKRF | c.1672C>A p.L558M | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.67); called by muse, mutect2
- NKRF | c.736T>C p.C246R | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- NPY5R | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NRK | c.2647C>A p.P883T | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NSDHL | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.393); called by muse, mutect2
- NUP205 | c.4852C>T p.Q1618* | Nonsense Mutation (SNP) | VAF 21/166 reads (13%) | called by muse, mutect2, varscan2
- OR11H12 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 135/388 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- OR1M1 | c.107T>G p.L36R | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- OR2G6 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR2M3 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- OR56A1 | c.627G>T p.L209F | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- OTOG | c.4345del p.Q1449Rfs*73 | Frame Shift Del (DEL) | VAF 35/242 reads (14%) | called by mutect2, varscan2
- OTOG | c.6296G>T p.G2099V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PCDHGB2 | c.2333A>T p.Q778L | Missense Mutation (SNP) | VAF 75/392 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- PFDN4 | c.219T>G p.D73E | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2
- PGK1 | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PGRMC1 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PIK3C2G | c.2422G>T p.E808* (on ENST00000676171; = p.E767* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 79/219 reads (36%) | called by muse, mutect2, varscan2
- PJA1 | c.1318T>A p.Y440N (on ENST00000361478 / NM_145119.4; = p.Y252N on NM_022368.5) | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.048); called by muse, mutect2
- PKHD1L1 | c.1948A>G p.T650A | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- PKHD1L1 | c.10307T>G p.I3436S | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, varscan2
- PKHD1L1 | c.10571A>G p.K3524R | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POTEH | c.1388A>T p.H463L | Missense Mutation (SNP) | VAF 109/1487 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- PRKAG1 | c.763_765del p.Y255del | In Frame Del (DEL) | VAF 31/137 reads (23%) | called by mutect2, pindel, varscan2
- PRKCE | c.389A>T p.D130V | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PRKX | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PROX1 | c.1527A>C p.R509S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPRD | c.893C>A p.A298E | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- RDX | c.1312A>T p.K438* | Nonsense Mutation (SNP) | VAF 40/254 reads (16%) | called by muse, varscan2
- REELD1 | c.732G>C p.E244D | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- RESF1 | c.2008A>T p.M670L | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RIBC1 | c.1135C>A p.R379S | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPTN | c.622A>G p.K208E | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- RXRG | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.14087C>A p.A4696D | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RYR3 | c.10491C>A p.N3497K (on ENST00000389232; = p.N3498K on NM_001036.6) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SAMD10 | c.346G>C p.V116L | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); called by muse, mutect2
- SELL | c.742G>T p.G248W (on ENST00000650983; = p.G235W on NM_000655.5) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGCA | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SIX2 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 48/474 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC39A10 | c.346del p.A116Qfs*20 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by mutect2, pindel, varscan2
- SLC9A6 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SMC6 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- SNRK | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SNX12 | c.50A>C p.Q17P | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SNX25 | c.1162T>A p.Y388N | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA31A1 | c.1402C>A p.Q468K | Missense Mutation (SNP) | VAF 87/726 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- SPATA31D1 | c.1705C>G p.Q569E | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- STARD7 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- STC2 | c.40T>A p.L14M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, varscan2
- SULF1 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.027); called by muse, mutect2
- SUPT20HL1 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SYCP1 | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- TBC1D9B | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TNR | c.2481G>T p.R827S | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- TTN | c.18203C>G p.A6068G (on ENST00000591111; = p.A5141G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | PolyPhen possibly damaging (0.795); called by muse, mutect2
- TXNDC16 | c.1654A>T p.K552* | Nonsense Mutation (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- VSIG1 | c.412+1G>C p.X138_splice | Splice Site (SNP) | VAF 13/144 reads (9%) | called by muse, mutect2
- VWDE | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WBP2NL | c.449G>C p.S150T | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- WDFY3 | c.2389C>T p.L797F | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- WDR19 | c.2176C>T p.L726F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, varscan2
- XYLT1 | c.2404dup p.T802Nfs*52 | Frame Shift Ins (INS) | VAF 40/289 reads (14%) | called by mutect2, pindel, varscan2
- ZFYVE26 | c.1134G>C p.Q378H | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.144); called by muse, mutect2
- ZNF425 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF43 | c.350A>G p.D117G | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF536 | c.3742C>A p.L1248M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); called by muse, mutect2
- ZNF543 | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ZNF675 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ZSCAN1 | c.182C>A p.T61K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ZSCAN10 | c.1291C>A p.Q431K (on ENST00000252463; = p.Q486K on NM_032805.3) | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZSCAN12 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 48/184 reads (26%) | called by muse, mutect2, varscan2
- ZWINT | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.025); called by muse, mutect2
- ZXDB | c.2392G>T p.G798C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, varscan2
- ZZEF1 | c.1857G>T p.R619S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- A1BG | c.1383G>T p.G461= | Silent (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- ABCF2 | c.75A>G p.K25= | Silent (SNP) | VAF 36/328 reads (11%) | called by muse, mutect2, varscan2
- ACTL6A | c.837T>A p.A279= | Silent (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- AHSG | c.723A>T p.A241= | Silent (SNP) | VAF 26/202 reads (13%) | called by muse, mutect2, varscan2
- ANGPTL3 | c.171T>A p.L57= | Silent (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- CAPN5 | c.516G>T p.V172= (on ENST00000456580; = p.V132= on NM_004055.5) | Silent (SNP) | VAF 55/373 reads (15%) | called by muse, mutect2, varscan2
- CCDC74B | c.966G>T p.T322= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as rs755279496, COSV100134202; called by muse, mutect2, varscan2
- CCNQ | c.678C>A p.T226= | Silent (SNP) | VAF 23/400 reads (6%) | catalogued as rs781857488; called by muse, mutect2
- CDH11 | c.2331T>A p.P777= | Silent (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- EPG5 | c.4536G>T p.L1512= | Silent (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- EPN3 | c.15A>C p.A5= | Silent (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- EPPK1 | c.4965C>G p.P1655= | Silent (SNP) | VAF 62/759 reads (8%) | called by muse, mutect2
- EYS | c.6477C>A p.P2159= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- FANCA | c.4305C>T p.A1435= | Silent (SNP) | VAF 56/301 reads (19%) | called by muse, mutect2, varscan2
- FCHO1 | c.780G>A p.R260= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- FNDC3B | c.3417C>T p.S1139= | Silent (SNP) | VAF 45/285 reads (16%) | catalogued as rs147667100; called by muse, mutect2, varscan2
- GANC | c.2616T>G p.S872= | Silent (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- GRIN2B | c.3657C>T p.P1219= | Silent (SNP) | VAF 67/214 reads (31%) | catalogued as rs200345385; called by muse, mutect2, varscan2
- HMMR | c.312G>A p.R104= | Silent (SNP) | VAF 51/267 reads (19%) | called by muse, varscan2
- HUWE1 | c.2628C>T p.C876= | Silent (SNP) | VAF 20/384 reads (5%) | catalogued as rs781888845; ClinVar: likely benign; called by muse, mutect2
- IGHV3-16 | c.108C>A p.S36= | Silent (SNP) | VAF 112/335 reads (33%) | called by muse, mutect2, varscan2
- IGLL5 | c.165A>T p.S55= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs1207543596; called by muse, mutect2, varscan2
- IGLV1-44 | c.69G>T p.L23= | Silent (SNP) | VAF 13/112 reads (12%) | called by muse, varscan2
- ILK | c.756A>T p.P252= | Silent (SNP) | VAF 113/681 reads (17%) | called by muse, mutect2, varscan2
- INTS1 | c.4563C>T p.V1521= | Silent (SNP) | VAF 25/234 reads (11%) | called by muse, mutect2, varscan2
- KCNB2 | c.1218T>A p.V406= | Silent (SNP) | VAF 17/311 reads (5%) | called by muse, mutect2
- KCNIP1 | c.171C>A p.T57= (on ENST00000411494 / NM_001034837.3; = p.T46= on NM_014592.4) | Silent (SNP) | VAF 34/122 reads (28%) | called by muse, varscan2
- KIAA1549L | c.4317C>A p.A1439= (on ENST00000321505; = p.A1736= on NM_012194.3) | Silent (SNP) | VAF 37/308 reads (12%) | catalogued as COSV100380932; called by muse, mutect2, varscan2
- KRTAP2-2 | c.12C>A p.S4= | Silent (SNP) | VAF 20/231 reads (9%) | called by muse, varscan2
- LRP4 | c.1701C>A p.T567= | Silent (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- LRRC30 | c.510C>T p.L170= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs751900239; called by muse, mutect2, varscan2
- MRTFA | c.1998C>T p.P666= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs751595077; called by mutect2, varscan2
- MUC16 | c.14610C>A p.T4870= | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- MYH1 | c.2520C>A p.I840= | Silent (SNP) | VAF 42/246 reads (17%) | called by muse, mutect2, varscan2
- MYO7B | c.477G>A p.E159= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1854A>G p.K618= | Silent (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2, varscan2
- OR10X1 | c.744G>A p.E248= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as rs767058852, COSV100936623; called by muse, mutect2, varscan2
- OR4Q2 | c.234G>T p.T78= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- OR8K3 | c.429G>T p.V143= | Silent (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- PCDH19 | c.447G>T p.P149= | Silent (SNP) | VAF 58/595 reads (10%) | catalogued as rs1193211185; called by muse, mutect2
- PCDHB3 | c.1533C>A p.G511= | Silent (SNP) | VAF 113/698 reads (16%) | called by muse, mutect2, varscan2
- PGP | c.46C>T p.L16= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- PLXNA3 | c.1824G>T p.G608= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs782615858; called by muse, mutect2
- PNRC1 | c.507C>G p.P169= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- POTEE | c.2523C>G p.S841= | Silent (SNP) | VAF 60/498 reads (12%) | catalogued as COSV100387692; called by muse, mutect2, varscan2
- PPP4R3C | c.51G>A p.E17= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs184287451; called by muse, mutect2
- PXDNL | c.2496C>T p.C832= | Silent (SNP) | VAF 40/365 reads (11%) | called by muse, mutect2, varscan2
- RBM4B | c.540G>A p.T180= | Silent (SNP) | VAF 36/250 reads (14%) | catalogued as rs1453154949; called by muse, mutect2, varscan2
- REV1 | c.1590A>G p.K530= | Silent (SNP) | VAF 35/223 reads (16%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1626G>T p.T542= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs758230491, COSV53707326; called by muse, mutect2, varscan2
- RYR3 | c.4854C>A p.A1618= | Silent (SNP) | VAF 52/213 reads (24%) | called by muse, mutect2, varscan2
- SHROOM2 | c.3267C>T p.V1089= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- SLC16A5 | c.748C>T p.L250= | Silent (SNP) | VAF 30/171 reads (18%) | called by muse, mutect2, varscan2
- SLC22A12 | c.840A>T p.A280= | Silent (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- SLC27A6 | c.306G>C p.L102= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as rs1197089385; called by muse, mutect2, varscan2
- STAG1 | c.1897C>T p.L633= | Silent (SNP) | VAF 12/277 reads (4%) | called by muse, mutect2
- STAG2 | c.1476G>T p.L492= | Silent (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2
- THAP8 | c.447C>A p.T149= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- TOX | c.1176C>A p.L392= | Silent (SNP) | VAF 50/225 reads (22%) | called by muse, mutect2, varscan2
- TRIM58 | c.1140G>T p.G380= | Silent (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.80814T>C p.G26938= (on ENST00000591111; = p.G19514= on NM_003319.4) | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- TXNDC16 | c.2106A>G p.V702= | Silent (SNP) | VAF 38/438 reads (9%) | called by muse, mutect2
- VLDLR | c.342C>A p.R114= | Silent (SNP) | VAF 58/289 reads (20%) | called by muse, mutect2, varscan2
- VSNL1 | c.502C>T p.L168= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- VWA5B2 | c.546C>T p.F182= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as rs1176319316; called by muse, mutect2
- WDR90 | c.1290G>A p.R430= | Silent (SNP) | VAF 25/170 reads (15%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4104G>C p.V1368= | Silent (SNP) | VAF 62/284 reads (22%) | called by muse, varscan2
- AC024940.1 | n.4324G>C | RNA (SNP) | VAF 107/413 reads (26%) | called by muse, mutect2, varscan2
- AC092675.1 | n.432G>T | RNA (SNP) | VAF 35/294 reads (12%) | called by muse, mutect2
- AC092675.1 | n.430A>T | RNA (SNP) | VAF 33/287 reads (11%) | called by muse, mutect2
- ACBD5 | chr10:27195945 C>G | 3'Flank (SNP) | VAF 6/70 reads (9%) | catalogued as rs1475586677; called by muse, mutect2
- ACHE | chr7:100896679 G>A | 5'Flank (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- AL590867.2 | n.427del | RNA (DEL) | VAF 17/144 reads (12%) | catalogued as rs747858319; called by mutect2, pindel, varscan2
- ARL13A | c.*352C>G | 3'UTR (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- ARMCX4 | c.1038+2982_1038+2983insT | Intron (INS) | VAF 11/91 reads (12%) | called by mutect2, varscan2
- C8orf34 | c.327+141A>T | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- CD200 | c.*38T>A | 3'UTR (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- CLDN16 | c.-41G>T | 5'UTR (SNP) | VAF 59/229 reads (26%) | catalogued as rs149955797; called by muse, mutect2, varscan2
- CRYGC | c.*39A>T | 3'UTR (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- EMC4 | c.201+100G>C | Intron (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- GCG | chr2:162143332 T>C | 3'Flank (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- HSPB1 | c.*43T>G | 3'UTR (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- MMP25 | c.662-1176G>C | Intron (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- MYADML | n.818G>A | RNA (SNP) | VAF 53/331 reads (16%) | called by muse, mutect2, varscan2
- MYO7A | c.6354+227G>T | Intron (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157587 G>A | 3'Flank (SNP) | VAF 36/635 reads (6%) | catalogued as rs782224131; called by muse, mutect2
- PDE4D | c.456-1275A>G | Intron (SNP) | VAF 42/248 reads (17%) | called by muse, mutect2, varscan2
- PLA2G6 | c.1592-23G>A | Intron (SNP) | VAF 11/96 reads (11%) | catalogued as rs764002301; called by muse, mutect2, varscan2
- PRSS40A | n.142-2183C>A | Intron (SNP) | VAF 32/279 reads (11%) | called by muse, mutect2, varscan2
- SC5D | c.343+16G>A | Intron (SNP) | VAF 45/264 reads (17%) | catalogued as rs1426590921; called by muse, mutect2, varscan2
- SLC25A51P4 | n.704A>G | RNA (SNP) | VAF 52/226 reads (23%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18576C>A | Intron (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- SNRNP200 | c.5755-34C>A | Intron (SNP) | VAF 43/353 reads (12%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210164140 T>C | 3'Flank (SNP) | VAF 8/44 reads (18%) | called by muse, varscan2
- TAGLN3 | c.*7del | 3'UTR (DEL) | VAF 55/308 reads (18%) | called by mutect2, pindel, varscan2
- TAZ | c.284+37G>A | Intron (SNP) | VAF 21/312 reads (7%) | catalogued as rs782762126; called by muse, mutect2
- TMEM135 | c.*672C>T | 3'UTR (SNP) | VAF 63/427 reads (15%) | catalogued as rs759157581; called by muse, mutect2, varscan2
- TSPAN19 | c.*18G>C | 3'UTR (SNP) | VAF 64/206 reads (31%) | catalogued as COSV101468065, COSV70814242; called by muse, mutect2, varscan2
- TTC9C | c.-302G>C | 5'UTR (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- UMPS | c.*4204A>G | 3'UTR (SNP) | VAF 60/315 reads (19%) | catalogued as rs958873460; called by muse, mutect2, varscan2
- UNC5A | c.722-640T>G | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- VCPKMT | c.266+14G>C | Intron (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
